Surgical pathology report (de-identified scan), TCGA case TCGA-CV-6961, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-6961-01A (Primary Tumor).

[page 1 of 3]
SUPPLEMENTAL REPORT

DIAGNOSIS:

- (B) ANTERIOR FLOOR OF MOUTH, ANTERIOR GLOSSECTOMY, ANTERIOR MANDIBLE
RESECTION:
INVASIVE POORLY DIFFERENTIATED SQUAMOUS CARCINOMA INVADING MANDIBLE.
(SEE COMMENT)
Bone margins of resection free of tumor.

COMMENT:

This supplemental report is being issued to give the results of additional sections submitted for decalcification. Invasion of the mandible was already reported in the original diagnosis. The additional information provided in this supplemental report is that the mandibular margins of resection are free of tumor.

GROSS DESCRIPTION:

- (B) ANTERIOR FLOOR OF MOUTH, ANTERIOR GLOSSECTOMY, ANTERIOR MANDIBLE
RESECTION -
SECTION CODE: B25, B27, right and left posterior mandibular margins, en face; B26, B28, sections through bone and tumor at the midline of anterior mandible.

Entire report and diagnosis completed by:
Report released by:

ENTIRE REPORT ELECTRONICALLY SIGNED BY:

DIAGNOSIS

- (A) BIOPSY FLOOR OF MOUTH:
FRAGMENTS OF SQUAMOUS CARCINOMA.
(B) ANTERIOR FLOOR OF MOUTH, ANTERIOR GLOSSECTOMY, ANTERIOR MANDIBLE
RESECTION:

[page 2 of 3]
INVASIVE POORLY DIFFERENTIATED SQUAMOUS CARCINOMA OF THE FLOOR OF THE MOUTH (1.8 CM) WITH INVASION OF TONGUE, MANDIBLE AND EXTENSION INTO SUBCUTANEOUS TISSUE AND SKIN ATTACHED TO ANTERIOR SURFACE OF MANDIBLE.

SEVERE SQUAMOUS DYSPLASIA/SQUAMOUS CARCINOMA IN SITU INVOLVING RIGHT POSTERIOR TONGUE MUCOSAL MARGIN OF RESECTION.

Other mucosal margins of resection, soft tissue margins and skin margin of resection free of tumor.

Right submandibular lymph node, no tumor present.

Right and left submandibular salivary glands with extensive atrophy consistent with therapy effect.

Sections of bone pending decalcification, supplemental report to follow.

(C) RIGHT JUGULAR DIGASTRIC LYMPH NODE:

One lymph node, no tumor present.

(D) #31 TOOTH ROOT:

Fragment of tooth, gross diagnosis only.

Entire report and diagnosis completed by:

Report released by:

GROSS DESCRIPTION

(A) BIOPSY FLOOR OF MOUTH - Irregular fragments of tan-gray tissue ranging from 0.7 to 0.1 cm in the largest dimension. The largest fragment is bisected and the entire specimen is submitted in toto for frozen section as A.

*FS/DX: FRAGMENTS OF SQUAMOUS CARCINOMA.

(B) ANTERIOR FLOOR OF MOUTH, ANTERIOR GLOSSECTOMY, ANTERIOR MANDIBLE RESECTION - A 7.0 x 6.5 x 5.2 cm specimen composed of anterior portion of tongue (6.0 x 5.0 x 1.8 cm), anterior mandible resection with anterior floor of mouth (6.5 x 4.7 x 3.0 cm), one portion of skin and subcutaneous tissue (6.0 x 5.0 x 0.8 cm) covering the anterior portion of the mandible, and bilateral submandibular tan soft tissue possibly salivary glands (4.0 x 3.0 x 1.5 cm each).

An ulcerated necrotic lesion (2.5 x 2.0 cm) is present in the anterior floor of mouth extending into the tongue forming a fairly defined tan-yellow soft mass (2.0 x 1.5 x 1.1 cm), approximately 1.2 cm from the posterior muscle margin of the tongue. The lesion of the anterior floor of mouth also extends to the anterior portion of the mandible into the subcutaneous tissue of the skin forming a pink-yellow necrotic nodule (1.5 x 1.3 x 2.0 cm), 1.0 cm from the closest right skin margin. The lesion in the anterior floor of the mouth is 0.6 cm from the closest right gingival mucosal margin. Bilateral possible submandibular salivary glands are grossly unremarkable.

Representative mucosal margins are submitted for frozen section diagnosis. The remaining mucosal margin and representative sections of the lesion are submitted for permanent sections. Sections of the lesion through the anterior floor of mouth and mandible, and the posterior margin of the mandible (bilateral) will be submitted after bone decalcification.

[page 3 of 3]
[REDACTED]

INK CODE: Blue-right mucosal margin; red-left mucosal margin; yellow-anterior mucosal and superior skin margin; blue-right skin margin; green-posterior margin of the tongue; black-muscular margin of the specimen.

SECTION CODE: B1, left side posterior mucosa, tongue, en face, frozen section; B2, left side, posterior mucosa, en face, frozen section; B3, left side posterior mucosa, en face, frozen section; B4, right side, posterior mucosa, tongue, en face, frozen section; B5, right side posterior mucosa, en face, frozen section; B6, right side mucosa, (gingiva), en face, frozen section; B6, right side mucosa (gingiva), en face, frozen section; B7, right side mucosa (gingiva), en face, frozen section; B8, right side mucosa (gingiva), en face, frozen section; B9-B12, anterior mucosal margin, en face, submitted from right to left; B13-B15, left mucosal margin, en face, submitted from anterior to posterior; B16, subcutaneous nodule with closest right side of skin margin; B17, subcutaneous necrotic mass with superior skin margin; B18, subcutaneous nodule; B19-B20, floor of mouth lesion extending to tongue; B21, lesion extending into tongue to the closest posterior muscle margin; perpendicular section; B22, representative muscle margin of the base of the specimen, perpendicular section; B23, representative section, right submandibular tissue; B24, representative section, left submandibular gland. A portion of the lesion and normal tongue is submitted for research. [REDACTED]

*FS/DX: FOCAL SEVERE SQUAMOUS DYSPLASIA/SQUAMOUS CARCINOMA IN SITU AT RIGHT POSTERIOR TONGUE MUCOSAL MARGIN OF RESECTION. OTHER MUCOSAL MARGINS SAMPLED FREE OF TUMOR. [REDACTED]

(C) RIGHT JUGULAR DIGASTRIC LYMPH NODE - One segment of adipose tissue (1.2 x 1.0 x 0.3 cm) with one tan soft lymph node identified measuring 0.8 x 0.5 x 0.3 cm. The lymph node is entirely submitted in C. [REDACTED]

(D) #31 TOOTH ROOT - One fragment of the root of a tooth (0.9 x 0.5 x 0.3 cm). No gross lesion identified. Gross examination only. [REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file db04c9f1-5446-4c36-b8b1-f4ad91fafacb (TCGA-CV-6961.812BFA73-5372-4C17-B046-475873D5656C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).